Somatic mutation profile of tumor specimen TCGA-G4-6297-01A (aliquot TCGA-G4-6297-01A-11D-1719-10) from TCGA case TCGA-G4-6297, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IV; Age at diagnosis: 55.0 years (20,103 days).
Specimen TCGA-G4-6297-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a27d58e3-0465-4592-91d0-fa07e26d61b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6297-10A (Blood Derived Normal), aliquot TCGA-G4-6297-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc630d1b-ac8d-4383-b73f-9cf2fb08242b

The open-access MAF lists 93 somatic variants for this specimen: 67 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 24, Nonsense Mutation 7, Frame Shift Del 3, Intron 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3184C>T p.Q1062* | Nonsense Mutation (SNP) | VAF 63/231 reads (27%) | catalogued as rs1554084818, CD961771, CM106365, COSV57341493; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 77/108 reads (71%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 40/166 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV55874903, COSV99836298; called by muse, mutect2, varscan2
- TP53 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587782620, CM132087, COSV52665025, COSV53025766, COSV53135444, COSV53176166; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACTL7B | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1330211221, COSV65927287; called by muse, mutect2, varscan2
- ADAM10 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 149/382 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53051305; called by muse, mutect2, varscan2
- ADAMTS1 | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758996929, COSV53168480; called by muse, mutect2, varscan2
- AGBL4 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 80/221 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs577993447, COSV61892347; called by muse, mutect2, varscan2
- ALG3 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as rs867376445, COSV56611286, COSV56613425; called by muse, mutect2, varscan2
- ANGPT4 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 161/337 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs775169357, COSV101124720, COSV67921423; called by muse, mutect2, varscan2
- APC | c.4466del p.L1489Yfs*18 | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | catalogued as COSV57327796; called by mutect2, pindel, varscan2
- BIRC6 | c.7265C>T p.A2422V | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.209); catalogued as COSV70198625; called by muse, mutect2
- BMP3 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 36/187 reads (19%) | catalogued as COSV51083460, COSV51085207; called by muse, mutect2, varscan2
- BPIFB2 | c.1262T>A p.L421H | Missense Mutation (SNP) | VAF 383/646 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50064295; called by muse, mutect2, varscan2
- C1QL2 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV55606602; called by muse, mutect2
- COL18A1 | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs375087150, COSV62700991, COSV62701918, COSV62703565; called by muse, mutect2, varscan2
- COL4A6 | c.3956G>C p.G1319A | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57865236, COSV57867996; called by muse, mutect2, varscan2
- CSMD2 | c.7975G>T p.G2659* | Nonsense Mutation (SNP) | VAF 24/122 reads (20%) | catalogued as COSV53907663, COSV53907909; called by muse, mutect2, varscan2
- CSTF2 | c.1237C>T p.R413* | Nonsense Mutation (SNP) | VAF 92/267 reads (34%) | catalogued as rs748719204, COSV65893806; called by muse, mutect2, varscan2
- CUTC | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs920986260, COSV65081769; called by muse, mutect2, varscan2
- CUX1 | c.608-2A>C p.X203_splice (on ENST00000292535 / NM_181552.4; = p.X214_splice on NM_001913.5) | Splice Site (SNP) | VAF 37/174 reads (21%) | catalogued as COSV52897959; called by muse, mutect2, varscan2
- DIRAS3 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63970685; called by muse, mutect2, varscan2
- DLX5 | c.68C>A p.T23K | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as COSV56032317; called by muse, mutect2, varscan2
- ELFN2 | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 157/292 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs564408490, COSV68744446; called by muse, mutect2, varscan2
- ELOVL3 | c.441C>A p.Y147* | Nonsense Mutation (SNP) | VAF 61/197 reads (31%) | catalogued as COSV64174428; called by muse, mutect2, varscan2
- EXPH5 | c.1777A>T p.K593* | Nonsense Mutation (SNP) | VAF 14/157 reads (9%) | catalogued as COSV56201688; called by muse, mutect2
- FIG4 | c.2713C>T p.R905C | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs754970037, COSV57787182; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMD6 | c.1033C>T p.Q345* (on ENST00000344768 / NM_001267046.2; = p.Q337* on NM_152330.4) | Nonsense Mutation (SNP) | VAF 34/67 reads (51%) | catalogued as COSV61087731; called by muse, mutect2, varscan2
- GJD2 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.732); catalogued as rs376923298; called by muse, mutect2, varscan2
- GREB1 | c.4346G>A p.R1449Q | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs371972292, COSV52199653; called by muse, mutect2, varscan2
- GRIK5 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV53477978; called by muse, mutect2, varscan2
- KIRREL3 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs1471330812, COSV69384269; called by muse, mutect2, varscan2
- LRG1 | c.722T>C p.L241P | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100014797; called by muse, mutect2
- LRRK2 | c.2404A>G p.S802G | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs774639952, COSV54151939; called by muse, mutect2, varscan2
- MBNL2 | c.1100A>T p.E367V (on ENST00000376673 / NM_001382666.1; = p.E355V on NM_207304.3 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/367 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); catalogued as COSV100600363; called by muse, mutect2
- MS4A15 | c.445G>C p.A149P (on ENST00000405633 / NM_001098835.2; = p.A56P on NM_152717.3) | Missense Mutation (SNP) | VAF 88/211 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV61961177; called by muse, mutect2, varscan2
- MYH15 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs200291167, COSV56309032, COSV56322346; called by muse, mutect2, varscan2
- NDUFS1 | c.1088_1095del p.S363Ffs*4 | Frame Shift Del (DEL) | VAF 22/102 reads (22%) | catalogued as COSV51909350; called by mutect2, pindel, varscan2
- NLRP10 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs776023158, COSV60780109; called by muse, mutect2, varscan2
- OPLAH | c.2161G>T p.V721L | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.359); catalogued as rs782158791, COSV70677850; called by muse, mutect2, varscan2
- OTUB2 | c.38G>A p.C13Y | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0.35); catalogued as COSV52573316; called by muse, mutect2, varscan2
- PAF1 | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.565); catalogued as COSV55393656; called by muse, mutect2, varscan2
- PASD1 | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 134/936 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.042); catalogued as COSV100949271; called by muse, varscan2
- PCDHB16 | c.2096C>T p.S699L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV53361594, COSV53368932; called by muse, mutect2
- PDZRN4 | c.2800G>A p.E934K (on ENST00000402685 / NM_001164595.2; = p.E676K on NM_013377.4) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54199851; called by muse, mutect2, varscan2
- PHF20L1 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs759962456, COSV55191922; called by muse, mutect2, varscan2
- PPIE | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as rs776933148, COSV60971308; called by muse, mutect2, varscan2
- PRAMEF12 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 59/234 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs377506368; called by muse, mutect2, varscan2
- PRDM16 | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV54588619; called by muse, mutect2
- RASL11B | c.314A>C p.N105T | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV50535046; called by muse, mutect2, varscan2
- RCC2 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 67/362 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64905752; called by muse, mutect2, varscan2
- SEC14L3 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV53179044; called by muse, mutect2, varscan2
- SLC25A6 | c.36C>A p.F12L | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as COSV67317685; called by muse, mutect2, varscan2
- SLC26A9 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769381035, COSV61602420; called by muse, mutect2, varscan2
- SSR1 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs777732061, COSV55202918; called by muse, mutect2, varscan2
- STXBP5L | c.2711G>A p.R904Q | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs566220337, COSV56511686; called by muse, mutect2, varscan2
- TBC1D31 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs763893402, COSV54865756, COSV99782448; called by muse, mutect2, varscan2
- TEX37 | c.458T>C p.L153P | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57555725; called by muse, mutect2, varscan2
- TGM7 | c.641C>A p.S214Y | Missense Mutation (SNP) | VAF 63/170 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV71772762; called by muse, mutect2, varscan2
- TIMELESS | c.3455-1G>A p.X1152_splice | Splice Site (SNP) | VAF 23/242 reads (10%) | catalogued as COSV57511028; called by muse, mutect2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 19/126 reads (15%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TTN | c.21716G>T p.R7239L (on ENST00000591111; = p.R6312L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/225 reads (36%) | PolyPhen benign (0.057); catalogued as rs374344734, COSV60020757; called by muse, mutect2, varscan2
- USP26 | c.2617G>T p.D873Y | Missense Mutation (SNP) | VAF 84/259 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV63708637; called by muse, mutect2, varscan2
- WDR17 | c.3035C>T p.A1012V | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs149711744; called by muse, mutect2, varscan2
- XRN1 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs772740589, COSV53807970; called by muse, mutect2, varscan2
- ZDBF2 | c.5449C>A p.L1817I | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV65625220; called by muse, mutect2, varscan2
- TPCN2 | c.1788dup p.G597Wfs*6 | Frame Shift Ins (INS) | VAF 118/361 reads (33%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.2298G>A p.K766= | Silent (SNP) | VAF 71/317 reads (22%) | catalogued as COSV61261944; called by muse, mutect2, varscan2
- CATSPERE | c.255C>G p.G85= | Silent (SNP) | VAF 299/956 reads (31%) | catalogued as COSV63677621; called by muse, mutect2, varscan2
- CD5 | c.1443C>T p.N481= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as COSV57108575; called by muse, mutect2, varscan2
- CNTRL | c.2680C>T p.L894= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- CYP21A2 | c.93G>A p.P31= | Silent (SNP) | VAF 110/470 reads (23%) | catalogued as rs1283610597, COSV100926195; called by muse, mutect2, varscan2
- DMBX1 | c.1113C>T p.H371= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs199960312, COSV100760892, COSV63601955; called by muse, mutect2, varscan2
- FAM124A | c.111C>T p.S37= (on ENST00000322475 / NM_001242312.2; = p.S73= on NM_145019.4) | Silent (SNP) | VAF 83/259 reads (32%) | catalogued as rs1303307696, COSV54476161; called by muse, mutect2, varscan2
- GLI3 | c.480C>T p.S160= | Silent (SNP) | VAF 47/152 reads (31%) | catalogued as rs148660482; ClinVar: likely benign; called by muse, mutect2, varscan2
- H2BC5 | c.291G>A p.T97= | Silent (SNP) | VAF 33/163 reads (20%) | catalogued as COSV56800901; called by muse, mutect2, varscan2
- HMGB1 | c.447G>A p.A149= | Silent (SNP) | VAF 201/428 reads (47%) | catalogued as rs753022161, COSV58104651; called by muse, mutect2, varscan2
- KLHL14 | c.1875A>G p.P625= | Silent (SNP) | VAF 95/207 reads (46%) | catalogued as COSV63832212; called by muse, mutect2, varscan2
- LDLRAP1 | c.675G>A p.T225= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as rs926407411, COSV65473486; called by muse, mutect2, varscan2
- MSR1 | c.1077C>T p.H359= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs1193407986, COSV100026278, COSV50506936; called by muse, mutect2, varscan2
- MYBPC2 | c.678C>T p.Y226= | Silent (SNP) | VAF 152/450 reads (34%) | catalogued as rs80199747, COSV63093994; called by muse, mutect2, varscan2
- PEG3 | c.4236A>G p.E1412= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as COSV55625532, COSV55636235; called by muse, mutect2
- RABEP1 | c.1305C>T p.D435= | Silent (SNP) | VAF 80/140 reads (57%) | catalogued as rs1196144461, COSV52584656, COSV99336338; called by muse, mutect2, varscan2
- RABGAP1 | c.2412C>T p.A804= | Silent (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- SEPHS2 | c.1203G>A p.A401= | Silent (SNP) | VAF 71/156 reads (46%) | catalogued as rs945198560, COSV72100785; called by muse, mutect2, varscan2
- SOCS5 | c.1107C>T p.L369= | Silent (SNP) | VAF 114/391 reads (29%) | catalogued as rs1374974406, COSV60603802; called by muse, mutect2, varscan2
- SOX11 | c.333C>T p.A111= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV100431000; called by muse, mutect2
- SUSD6 | c.432A>G p.P144= | Silent (SNP) | VAF 66/114 reads (58%) | catalogued as rs1171351116, COSV61365239; called by muse, mutect2, varscan2
- TACR3 | c.315C>T p.I105= | Silent (SNP) | VAF 37/158 reads (23%) | catalogued as rs374928781, COSV59200938; called by muse, mutect2, varscan2
- TENM4 | c.5721C>T p.Y1907= | Silent (SNP) | VAF 179/362 reads (49%) | catalogued as rs768735704, COSV53625388; called by muse, mutect2, varscan2
- ZNF804A | c.1149C>T p.N383= | Silent (SNP) | VAF 57/195 reads (29%) | catalogued as rs1428087343, COSV100170698, COSV56446669; called by muse, mutect2, varscan2
- SLC35A2 | c.1163+11G>A | Intron (SNP) | VAF 46/145 reads (32%) | catalogued as COSV54430232; called by muse, mutect2, varscan2
- TTN | c.10303+1299T>A | Intron (SNP) | VAF 64/171 reads (37%) | catalogued as COSV60020771; called by muse, mutect2, varscan2
